Somatic mutation profile of tumor specimen ALCH-B287-TTP1-A (aliquot ALCH-B287-TTP1-A-1-0-D-A77Z-36) from ALCHEMIST case ALCH-B287, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.9 years (22,599 days).
Specimen ALCH-B287-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6107480-9dac-4dd6-bf2c-43b4adfec8e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B287-NB1-A (Blood Derived Normal), aliquot ALCH-B287-NB1-A-1-0-D-A77Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/010f22bb-7511-48c2-b416-90fec3334138

The open-access MAF lists 183 somatic variants for this specimen: 121 protein-altering or splice-affecting, 35 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 35, Intron 16, Frame Shift Del 5, 5'UTR 3, Splice Site 3, Nonsense Mutation 3, RNA 3, 3'UTR 3, Splice Region 2, 5'Flank 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 158/505 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ALK | c.872G>C p.R291P | Missense Mutation (SNP) | VAF 49/430 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.998); catalogued as COSV66557726, COSV66593660, COSV66594689; called by muse, mutect2, varscan2
- ANK2 | c.8188C>A p.P2730T | Missense Mutation (SNP) | VAF 56/526 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.036); catalogued as COSV100003581; called by muse, mutect2, varscan2
- ATRX | c.7016C>T p.T2339I | Missense Mutation (SNP) | VAF 38/334 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV64875073; called by muse, mutect2, varscan2
- BRDT | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs771728285; called by muse, mutect2, varscan2
- CASP5 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 90/505 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV52829825; called by muse, mutect2, varscan2
- CBLN2 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99504231; called by muse, mutect2
- CDK5RAP2 | c.5636G>T p.G1879V | Missense Mutation (SNP) | VAF 98/733 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV100575326; called by muse, mutect2, varscan2
- CFAP100 | c.265A>T p.M89L | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as rs750055856; called by muse, mutect2, varscan2
- DNAH6 | c.2915A>T p.H972L | Missense Mutation (SNP) | VAF 47/352 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1483802131; called by muse, mutect2, varscan2
- FLCN | c.367del p.Q123Rfs*7 | Frame Shift Del (DEL) | VAF 43/275 reads (16%) | catalogued as COSV99550545; called by mutect2, pindel, varscan2
- GALNT13 | c.1396-1G>T p.X466_splice | Splice Site (SNP) | VAF 14/93 reads (15%) | catalogued as COSV67242986; called by muse, mutect2, varscan2
- GLDC | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 78/985 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.753); catalogued as rs746744137; called by muse, mutect2
- GPR50 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs370636515, COSV54439599; called by muse, mutect2, varscan2
- ITSN2 | c.2711A>T p.Q904L | Missense Mutation (SNP) | VAF 57/260 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs373121938; called by muse, mutect2, varscan2
- KCNT1 | c.1919G>A p.R640H (on ENST00000488444; = p.R659H on NM_020822.3) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as rs754634573; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LTN1 | c.3133A>G p.I1045V | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs149946471; called by muse, mutect2, varscan2
- MEX3B | c.1360C>A p.H454N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV61663552; called by mutect2, varscan2
- MROH2A | c.2371C>T p.H791Y | Missense Mutation (SNP) | VAF 40/356 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.938); catalogued as rs1016621631; called by muse, mutect2, varscan2
- MYH1 | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 60/478 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV55438782; called by muse, mutect2, varscan2
- NUDT4 | c.539G>C p.R180T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV61463804; called by mutect2, varscan2
- PHF2 | c.2099C>T p.P700L | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs745947229, COSV63680602; called by muse, mutect2, varscan2
- PKD2L1 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 68/455 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754844314, COSV58394617; called by muse, mutect2, varscan2
- POT1 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 99/250 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs797045168, CM1412277, COSV62928287; ClinVar: risk factor / uncertain significance; called by muse, varscan2
- PRF1 | c.658G>C p.G220R | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776571416, CM012646, CM066189; called by muse, mutect2, varscan2
- RASA2 | c.2530A>G p.I844V | Missense Mutation (SNP) | VAF 25/240 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767988939; called by muse, varscan2
- RCAN2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 31/306 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.38); catalogued as COSV100149309; called by muse, mutect2, varscan2
- SLC4A1AP | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs768449191; called by muse, mutect2, varscan2
- TENM1 | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 64/553 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV64424887, COSV64430687; called by muse, mutect2, varscan2
- TP53BP1 | c.2768C>T p.P923L | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs759443391; called by muse, mutect2, varscan2
- TRMT44 | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 204/1018 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs201920958, COSV67664789; called by muse, mutect2, varscan2
- TRPC7 | c.524A>T p.Q175L | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs1041562468; called by muse, mutect2, varscan2
- TSHZ2 | c.2767C>G p.H923D | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV61590675; called by muse, mutect2, varscan2
- VCAN | c.9941G>T p.R3314L | Missense Mutation (SNP) | VAF 48/471 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763390705, COSV54110210, COSV54118403; called by muse, mutect2, varscan2
- XK | c.932C>A p.S311Y | Missense Mutation (SNP) | VAF 78/812 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs782799321; called by muse, mutect2
- ZNF716 | c.656del p.G219Afs*126 | Frame Shift Del (DEL) | VAF 26/266 reads (10%) | catalogued as COSV70781640; called by pindel, varscan2
- ZNF880 | c.446T>A p.I149N | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as rs915351547, COSV101425002; called by muse, mutect2
- ACACB | c.67T>C p.W23R | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACTRT1 | c.408C>A p.Y136* | Nonsense Mutation (SNP) | VAF 24/195 reads (12%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.2844del p.W948* | Frame Shift Del (DEL) | VAF 79/720 reads (11%) | called by mutect2, pindel, varscan2
- ADNP2 | c.2578A>T p.R860W | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- AGAP2 | c.2954C>T p.S985L (on ENST00000547588 / NM_001122772.2; = p.S629L on NM_014770.4) | Missense Mutation (SNP) | VAF 35/483 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- AGO4 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 47/452 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- ANK2 | c.3115C>T p.Q1039* | Nonsense Mutation (SNP) | VAF 21/304 reads (7%) | called by muse, mutect2
- ANKK1 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARAP2 | c.2618-1G>C p.X873_splice | Splice Site (SNP) | VAF 18/145 reads (12%) | called by muse, mutect2, varscan2
- BOC | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 59/501 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- C10orf82 | c.636G>T p.R212S | Missense Mutation (SNP) | VAF 40/379 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- CCDC168 | c.2833A>C p.S945R | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.867); called by muse, varscan2
- CDH10 | c.505G>C p.V169L | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2
- CDS1 | c.92A>G p.H31R | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- CFAP54 | c.5825G>A p.C1942Y | Missense Mutation (SNP) | VAF 32/404 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.422); called by muse, mutect2
- CLCN4 | c.698G>C p.C233S | Missense Mutation (SNP) | VAF 105/793 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CSMD3 | c.1628G>T p.C543F (on ENST00000297405 / NM_001363185.1; = p.C439F on NM_052900.3) | Missense Mutation (SNP) | VAF 57/691 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCDC1 | c.2700T>G p.S900R (on ENST00000597505 / NM_001367979.1; = p.S7R on NM_020869.3) | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- DDX6 | c.793C>T p.L265F | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2
- DICER1 | c.-45T>A | Splice Region (SNP) | VAF 126/509 reads (25%) | called by muse, mutect2, varscan2
- DLAT | c.1543G>T p.V515F | Missense Mutation (SNP) | VAF 66/403 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLC1 | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 51/467 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYRK4 | c.1133G>T p.R378I | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- EIF4G3 | c.2185G>T p.A729S | Missense Mutation (SNP) | VAF 66/518 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- EPB41L3 | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2
- EPHB6 | c.489C>G p.S163R | Missense Mutation (SNP) | VAF 139/851 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- EPM2A | c.122G>C p.R41T | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- ERVV-1 | c.1351C>A p.P451T | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- ESPL1 | c.5482G>T p.D1828Y | Missense Mutation (SNP) | VAF 36/322 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- FAM90A1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 104/1688 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FBXO38 | c.1874G>T p.R625L | Missense Mutation (SNP) | VAF 65/298 reads (22%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FMN1 | c.560C>G p.S187* | Nonsense Mutation (SNP) | VAF 31/211 reads (15%) | called by muse, mutect2, varscan2
- GDF9 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 62/728 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.081); called by muse, mutect2
- GIPR | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 61/572 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GTF3C1 | c.2071G>A p.V691M | Missense Mutation (SNP) | VAF 57/375 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HCN1 | c.1114C>A p.L372I | Missense Mutation (SNP) | VAF 249/1149 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- HUWE1 | c.8882-2A>C p.X2961_splice | Splice Site (SNP) | VAF 45/513 reads (9%) | called by muse, mutect2
- HUWE1 | c.2966G>A p.R989K | Missense Mutation (SNP) | VAF 66/546 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, varscan2
- IGHV3-74 | c.247G>C p.V83L | Missense Mutation (SNP) | VAF 122/580 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- KLHL32 | c.433T>A p.L145M | Missense Mutation (SNP) | VAF 62/328 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2
- MAGEB18 | c.705C>A p.F235L | Missense Mutation (SNP) | VAF 38/352 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- MAGEB5 | c.563A>T p.E188V | Missense Mutation (SNP) | VAF 40/328 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- MAP2K4 | c.536A>T p.E179V | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MEI1 | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 56/562 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2
- METTL8 | c.56A>G p.H19R | Missense Mutation (SNP) | VAF 80/448 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MGAM2 | c.5773C>A p.P1925T | Missense Mutation (SNP) | VAF 81/223 reads (36%) | SIFT tolerated, low confidence (0.24); called by muse, mutect2, varscan2
- MGAM2 | c.5774C>G p.P1925R | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- MUC16 | c.29332C>A p.P9778T | Missense Mutation (SNP) | VAF 60/550 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- MYH4 | c.3720G>T p.E1240D | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, varscan2
- NOS3 | c.685A>G p.T229A | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NUP205 | c.3103G>T p.A1035S | Missense Mutation (SNP) | VAF 42/478 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.37); called by muse, mutect2
- OR10W1 | c.622T>C p.S208P | Missense Mutation (SNP) | VAF 78/419 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OR52B6 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR52E4 | c.560C>A p.A187D | Missense Mutation (SNP) | VAF 52/307 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCMTD2 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 49/374 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PHRF1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.398); called by muse, mutect2
- PSMD8 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 61/491 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- PYROXD2 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); called by muse, mutect2
- RAD1 | c.74G>T p.R25M | Missense Mutation (SNP) | VAF 73/714 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- RANBP17 | c.313C>G p.Q105E | Missense Mutation (SNP) | VAF 46/292 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- RARRES2 | c.114C>G p.H38Q | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2
- RCE1 | c.289-3C>T | Splice Region (SNP) | VAF 42/384 reads (11%) | called by muse, mutect2, varscan2
- ROBO2 | c.36G>T p.M12I | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- RRH | c.111G>T p.M37I | Missense Mutation (SNP) | VAF 37/455 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- SBF1 | c.3989T>A p.L1330Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SEC23B | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 61/543 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SI | c.3254T>A p.I1085N | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLC17A4 | c.216C>G p.S72R | Missense Mutation (SNP) | VAF 95/818 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SLF2 | c.2545A>T p.I849F | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- SYN1 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 108/756 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TC2N | c.1174_1177del p.K392Wfs*9 | Frame Shift Del (DEL) | VAF 47/222 reads (21%) | called by mutect2, pindel, varscan2
- TCF7 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2
- TENM1 | c.2684C>A p.A895D | Missense Mutation (SNP) | VAF 68/470 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- TENM4 | c.4736C>A p.S1579Y | Missense Mutation (SNP) | VAF 36/434 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.454); called by muse, mutect2
- TEX10 | c.2776G>C p.A926P | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.028); called by muse, mutect2
- UBA6 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 24/283 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.07); called by muse, mutect2
- UTP25 | c.2267A>T p.K756I | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.121); called by muse, mutect2
- VPS53 | c.1109G>A p.G370E (on ENST00000571805 / NM_001366253.2; = p.G341E on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDFY3 | c.9790G>C p.E3264Q | Missense Mutation (SNP) | VAF 37/720 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- ZDBF2 | c.763A>G p.K255E | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.078); called by muse, mutect2
- ZIC3 | c.1286C>T p.T429I | Missense Mutation (SNP) | VAF 39/360 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZNF185 | c.1781C>T p.S594F | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.022); called by muse, mutect2
- ZNF729 | c.1653del p.A552Lfs*13 | Frame Shift Del (DEL) | VAF 48/420 reads (11%) | called by mutect2, varscan2
- ZNF808 | c.2280G>C p.E760D | Missense Mutation (SNP) | VAF 79/516 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ABCB5 | c.2916C>T p.L972= (on ENST00000404938 / NM_001163941.2; = p.L527= on NM_178559.6) | Silent (SNP) | VAF 16/394 reads (4%) | catalogued as rs1034934618; called by muse, mutect2
- ANO2 | c.630C>T p.Y210= (on ENST00000356134 / NM_001278597.3; = p.Y214= on NM_001278596.3) | Silent (SNP) | VAF 46/358 reads (13%) | catalogued as rs202136193; called by muse, mutect2, varscan2
- EIF2AK1 | c.81C>T p.I27= | Silent (SNP) | VAF 15/266 reads (6%) | catalogued as COSV52238524; called by muse, mutect2
- EPHB1 | c.2127C>A p.L709= | Silent (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- GUCY2C | c.3018G>A p.Q1006= | Silent (SNP) | VAF 42/425 reads (10%) | catalogued as rs1194096068, COSV99664100; called by muse, mutect2
- HECA | c.1344G>A p.V448= | Silent (SNP) | VAF 47/314 reads (15%) | called by muse, mutect2, varscan2
- HOXB7 | c.594C>T p.T198= | Silent (SNP) | VAF 49/463 reads (11%) | called by muse, mutect2, varscan2
- IGKV2-28 | c.105T>A p.P35= | Silent (SNP) | VAF 45/528 reads (9%) | called by muse, mutect2, varscan2
- KCNA6 | c.441C>T p.D147= | Silent (SNP) | VAF 45/406 reads (11%) | catalogued as COSV54975011; called by muse, mutect2, varscan2
- KIF5A | c.48C>T p.F16= | Silent (SNP) | VAF 83/881 reads (9%) | called by muse, mutect2
- MATN3 | c.621G>C p.A207= | Silent (SNP) | VAF 38/270 reads (14%) | called by muse, mutect2, varscan2
- MRAS | c.111C>A p.I37= | Silent (SNP) | VAF 11/135 reads (8%) | called by muse, mutect2
- NGFR | c.468C>T p.D156= | Silent (SNP) | VAF 34/305 reads (11%) | catalogued as rs980651699; called by muse, mutect2, varscan2
- NLGN4X | c.360G>T p.L120= | Silent (SNP) | VAF 81/695 reads (12%) | catalogued as COSV52039461; called by muse, mutect2, varscan2
- OR1D2 | c.378C>A p.I126= | Silent (SNP) | VAF 59/500 reads (12%) | called by muse, mutect2, varscan2
- ORAI1 | c.297C>T p.F99= | Silent (SNP) | VAF 42/526 reads (8%) | catalogued as COSV100345523; called by muse, mutect2
- OSBPL3 | c.357C>G p.T119= | Silent (SNP) | VAF 182/552 reads (33%) | catalogued as rs139450336; called by muse, mutect2, varscan2
- PIEZO1 | c.4767C>T p.T1589= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs772659837, COSV56344069; called by muse, mutect2
- PIWIL1 | c.1761G>A p.V587= | Silent (SNP) | VAF 102/900 reads (11%) | called by muse, mutect2, varscan2
- PTPRJ | c.1398C>T p.S466= | Silent (SNP) | VAF 50/281 reads (18%) | called by muse, mutect2, varscan2
- RASGRP2 | c.1233C>T p.T411= | Silent (SNP) | VAF 30/590 reads (5%) | catalogued as rs1399568887; called by muse, mutect2
- RDH5 | c.687G>A p.L229= | Silent (SNP) | VAF 60/227 reads (26%) | called by muse, mutect2, varscan2
- RNF128 | c.93G>A p.P31= | Silent (SNP) | VAF 44/256 reads (17%) | catalogued as COSV99718493; called by muse, mutect2, varscan2
- SERPINB2 | c.255C>A p.I85= | Silent (SNP) | VAF 63/553 reads (11%) | catalogued as COSV55091891; called by muse, mutect2, varscan2
- SLC25A25 | c.270G>A p.L90= | Silent (SNP) | VAF 36/323 reads (11%) | called by muse, mutect2, varscan2
- SLC2A10 | c.1209G>T p.R403= | Silent (SNP) | VAF 44/245 reads (18%) | called by muse, mutect2, varscan2
- SNAPC4 | c.2097C>T p.P699= | Silent (SNP) | VAF 24/170 reads (14%) | catalogued as rs749304060; called by muse, mutect2, varscan2
- SORCS1 | c.216C>T p.L72= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs775319854; called by muse, mutect2, varscan2
- TAS2R38 | c.228C>A p.I76= | Silent (SNP) | VAF 55/591 reads (9%) | called by muse, mutect2
- TNR | c.1710C>T p.Y570= | Silent (SNP) | VAF 27/183 reads (15%) | catalogued as rs746969510, COSV54899996; called by muse, mutect2, varscan2
- TOPAZ1 | c.807A>T p.A269= | Silent (SNP) | VAF 24/164 reads (15%) | called by muse, mutect2, varscan2
- Z83844.2 | c.396G>A p.E132= | Silent (SNP) | VAF 40/373 reads (11%) | catalogued as rs1227474092; called by muse, mutect2, varscan2
- ZFHX3 | c.4866C>A p.T1622= | Silent (SNP) | VAF 41/153 reads (27%) | called by muse, mutect2, varscan2
- ZNF273 | c.1179G>A p.K393= | Silent (SNP) | VAF 52/529 reads (10%) | catalogued as rs1167220001; called by muse, mutect2
- ZNF716 | c.639C>T p.Y213= | Silent (SNP) | VAF 96/286 reads (34%) | called by muse, varscan2
- AC058822.1 | c.1018-288234G>C | Intron (SNP) | VAF 74/645 reads (11%) | called by muse, mutect2, varscan2
- ATP7A | c.*37G>T | 3'UTR (SNP) | VAF 59/360 reads (16%) | called by muse, mutect2, varscan2
- CCL4L2 | c.191+108G>A | Intron (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- CSH2 | c.456+16G>A | Intron (SNP) | VAF 81/571 reads (14%) | called by muse, mutect2, varscan2
- DDX41 | c.139-110G>T | Intron (SNP) | VAF 52/190 reads (27%) | called by muse, mutect2, varscan2
- HTR3D | c.511+37T>A | Intron (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2
- IQSEC2 | c.738-10840del | Intron (DEL) | VAF 14/84 reads (17%) | called by mutect2, pindel
- KCNC3 | chr19:50334373 G>A | 5'Flank (SNP) | VAF 33/414 reads (8%) | called by muse, mutect2
- KYNU | c.902+2836C>G | Intron (SNP) | VAF 38/333 reads (11%) | catalogued as COSV51579004, COSV51581929, COSV99933990; called by muse, mutect2, varscan2
- LINC00602 | n.914C>A | RNA (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- MAGEA5 | n.54C>A | RNA (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- MBD4 | c.1665+43G>A | Intron (SNP) | VAF 35/289 reads (12%) | called by muse, mutect2, varscan2
- MGAM | c.4618+12910A>C | Intron (SNP) | VAF 42/520 reads (8%) | called by muse, mutect2
- MID1 | c.757-10779C>A | Intron (SNP) | VAF 18/198 reads (9%) | called by muse, mutect2
- MPV17 | c.71-4100C>G | Intron (SNP) | VAF 31/166 reads (19%) | called by muse, mutect2, varscan2
- OR6W1P | n.399C>T | RNA (SNP) | VAF 29/277 reads (10%) | catalogued as rs749845816; called by muse, mutect2, varscan2
- PAX4 | c.772-9T>C | Intron (SNP) | VAF 198/480 reads (41%) | called by mutect2, varscan2
- RNF135 | chr17:30971038 C>G | 5'Flank (SNP) | VAF 24/249 reads (10%) | called by muse, mutect2
- SETBP1 | c.*27G>A | 3'UTR (SNP) | VAF 25/141 reads (18%) | catalogued as rs1370292649; called by muse, mutect2, varscan2
- SLAMF7 | c.649+10T>C | Intron (SNP) | VAF 10/47 reads (21%) | catalogued as rs781745290; called by muse, mutect2, varscan2
- SMUG1 | c.285+60G>T | Intron (SNP) | VAF 18/55 reads (33%) | called by muse, varscan2
- STX3 | c.-20C>G | 5'UTR (SNP) | VAF 20/374 reads (5%) | called by muse, mutect2
- TM2D1 | c.-32G>C | 5'UTR (SNP) | VAF 20/140 reads (14%) | called by muse, mutect2, varscan2
- TMEM70 | c.*654G>A | 3'UTR (SNP) | VAF 47/186 reads (25%) | called by muse, mutect2, varscan2
- TYW5 | c.303+40C>G | Intron (SNP) | VAF 11/72 reads (15%) | catalogued as rs779564912; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23433C>T | Intron (SNP) | VAF 73/510 reads (14%) | catalogued as rs201940151; called by muse, mutect2, varscan2
- WDR44 | c.-30G>T | 5'UTR (SNP) | VAF 31/356 reads (9%) | called by muse, mutect2
